Surgical pathology report (de-identified scan), TCGA case TCGA-06-0184, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0184-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0184

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with headaches for 3 weeks; on imaging, large right frontal mass, partially enhancing and focally necrotic.

OPERATIVE DIAGNOSES

Craniotomy for brain lesion.

Operation/Specimen: Brain, resection

PATHOLOGICAL DIAGNOSIS:

Brain, right frontal, excision: Glioblastoma.
See comment.

COMMENT

The specimen is portions of cerebrum extensively infiltrated and effaced by an astrocytic neoplastic proliferation with frequent mitotic figures, microvascular cellular proliferation, and extensive zones of necrosis, some with pseudopalisading. There are also zones of hemorrhage with early organization.

Special stains to better characterize the tumor are being requested, and will be reported as an addendum.

PROCEDURES/ADDENDA

Immunohistology

Date Reported: [REDACTED]

Interpretation

MIB1 PROLIFERATION INDEX: 6%.

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates focal glial fibrillogenesis by the neoplastic cells. About 25% of the neoplastic nuclei over express the p53 protein. With the MIB1, a proliferation index of about 6% is determined in the more active areas.
The results support the diagnosis of glioblastoma.

[page 2 of 2]
GROSS DESCRIPTION

SPECIMEN: Tumor for permanent.

FIXATIVE: Saline.,,

GENERAL: A 6 x 4.5 x 1.5 cm. aggregate of multiple irregular fragments of gray-tan to gray-white fragments of brain tissue.

SECTIONS: A1-A5 - representative sections.

ICD-9(s):
191.1 191.1

Histo Data

Part A: Brain, resection

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt

Block

Ordered

Comment

mGFAP-DA x 1

1

These immunos are already

being done today. Thanks.

H/E x 1

1

MIB1-DA x 1

1

P53DO7 x 1

1

H/E x 1

2

H/E x 1

3

H/E x 1

4

H/E x 1

5

*** End of Report ***

Source: NCI Genomic Data Commons file 7bae8078-7599-4336-afdf-7fb1f72cea3e (TCGA-06-0184.CE516253-ACF1-4186-8998-DC089161E261.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).